Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2IR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2IR-01A (Primary Tumor).

[page 1 of 7]
100-0-3
Name: Carcinoma, squamous cell,
Address: Kuratitzky, NOS 8071/3
Site: Cervix, NOS C53.9
MR No.:
Service: GYNECOLOGY
Surgeon: 7/24/11

Surg. Path. No.:
DOB:
(Age):
Sex/Race: F WHITE
Location:
Hosp. No.:
Taken/Received:
Patient type:

DIAGNOSIS

UTERUS, CERVIX, RADICAL HYSTERECTOMY
- SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED, 6.2 CM IN GREATEST DIMENSION
- TUMOR INVADES TO A DEPTH OF 10 MM (TOTAL WALL THICKNESS 14 MM)
- EXTENSIVE LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED

PARAMETRIA, RADICAL HYSTERECTOMY - NO CARCINOMA IDENTIFIED

LYMPH NODE, PARAMETRIUM, RADICAL HYSTERECTOMY
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

PARAMETRIUM, RIGHT, BIOPSY - NO CARCINOMA IDENTIFIED

VAGINA, CUFF, MARGIN - FOCAL PARAKERATOSIS
- NO CARCINOMA OR DYSPLASIA IDENTIFIED

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY - MENSTRUAL ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY - MULTIPLE LEIOMYOMAS
- ADENOMYOSIS

OVARY, LEFT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO-OOPHORECTOMY - PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION (FS1, X1)
- NO CARCINOMA IDENTIFIED IN FOUR LYMPH NODES (0/4)

LYMPH NODES, RIGHT OBTURATOR, EXCISION (FS2, X2)
- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

LYMPH NODES, RIGHT EXTERNAL ILIAC (B), EXCISION (FS3, X3)
- NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

LYMPH NODES, LEFT PELVIC, EXCISION (FS5A, FS5B, X5)
- NO CARCINOMA IDENTIFIED IN NINE LYMPH NODES (0/9)

[page 2 of 7]
Name:

Surg. Path. No.:

DIAGNOSIS (continued)

LYMPH NODES, LEFT PERIAROTIC, EXCISION (FS6, X6)
- NO CARCINOMA IDENTIFIED IN FOUR LYMPH NODES (0/4)

LYMPH NODE, LEFT COMMON ILIAC, EXCISION (FS7, X7)
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LYMPH NODES, RIGHT COMMON ILIAC, EXCISION
- NO CARCINOMA IDENTIFIED
- NO LYMPH NODE IDENTIFIED (SPECIMEN ENTIRELY
SUBMITTED)

By this signature, I attest that the
above diagnosis is based upon my
personal examination of the slides
(and/or other material indicated in
the diagnosis), and that I have
reviewed and approved this report.

SPECIMEN(S) SUBMITTED

Part 1: FS1- LYMPH NODE, RIGHT EXTERNAL ILIAC
Part 2: X1- LYMPH NODE, RIGHT EXTERNAL ILIAC
Part 3: FS2- LYMPH NODE, RIGHT OBTURATOR
Part 4: X2- LYMPH NODE, RIGHT OBTURATOR
Part 5: FS3- LYMPH NODE, RIGHT EXTERNAL ILIAC (B)
Part 6: X3- LYMPH NODE, RIGHT EXTERNAL ILIAC (B)
Part 7: FS5A- LYMPH NODE, LEFT PELVIC
Part 8: FS5B- LYMPH NODE, LEFT PELVIC
Part 9: X5- LYMPH NODE, LEFT PELVIC
Part 10: FS6- LYMPH NODE, LEFT PARAAORTIC
Part 11: X6- LYMPH NODE, LEFT PARAAORTIC
Part 12: FS7- LYMPH NODE, LEFT COMMON ILIAC
Part 13: X7- LYMPH NODE, LEFT COMMON ILIAC
Part 14: LYMPH NODE, RIGHT COMMON ILIAC
Part 15: RIGHT PARAMETRIUM
Part 16: UTERUS, CERVIX, BSO

HISTORY

The patient is a year old white female with cervical carcinoma.
Operative procedure: Examination under anesthesia and lymph node
dissection.

[page 3 of 7]
Surg. Path. No.:

Name:

HISTORY (continued)

An intraoperative non-microscopic consultation was obtained and interpreted as: "#1, Right common iliac lymph node" - fat fibrous tissue only on gross examination; not frozen." by

"#2, uterus, bilateral ovaries, bilateral fallopian tubes, radical hysterectomy with BSO" - radical hysterectomy specimen with attached bilateral adnexae, cervix and vaginal cuff. Margin inked. Cervix involved circumferentially by a bulky tumor measuring 6.2 cm in greatest dimension. Tumor sampled for tumor bank and ; normal myometrium sampled for tumor bank. Uterus bivalved. Specimen placed in formalin fixative." by

FROZEN

FS1: Lymph nodes, right external iliac, dissection
- "No evidence of malignancy," by

FS2: Lymph nodes, right obturator, dissection
- "No evidence of malignancy," by

FS3: Lymph nodes, right external iliac, (CB) excision
- "No evidence of malignancy," by

FS5A&B: Lymph nodes, left pelvic, excision
- "No evidence of malignancy," by

FS6: Lymph nodes, left para-aortic, excision
- "No evidence of malignancy," by

FS7: Lymph nodes, left common iliac, excision
- "No evidence of malignancy," by

GROSS

The specimens are received in sixteen containers of formalin, each labeled with the patient's name. The first container is additionally labeled "right external iliac lymph nodes, FS1" and contains four irregularly-shaped tissue fragments which in aggregate measure ~2 x 1.5 x 0.5 cm. Entirely submitted as FS1. Jar 0.

The second container is additionally labeled "X1" and contains several irregularly-shaped adipose tissue fragments with attached staples which in aggregate measure ~3.5 x 2.0 x 0.7 cm. Several small, lymph node-like structures are identified ranging in size from 0.2 to 0.4 cm in greatest dimension. Entirely submitted as

[page 4 of 7]
Surg. Path. No.:

Name:

GROSS (continued)

X1. Jar 1.

The third container is additionally labeled "right obturator, FS2" and contains three lymph nodes that range in size from 1 to 1.5 cm in greatest dimension. Entirely submitted as FS2. Jar 0.

The fourth container is additionally labeled "X2" and contains several irregularly-shaped adipose tissue fragments which in aggregate measure ~4 x 2 x 1 cm. Upon examination, several lymph node-like structures are identified ranging in size from 0.2 to ~1.0 cm in greatest dimension. Entirely submitted as X2. Jar 1.

The fifth container is additionally labeled "FS3" and contains two lymph nodes measuring ~0.5 and 0.7 cm in greatest dimension each. Entirely submitted as FS3. Jar 0.

The sixth container is additionally labeled "X3" and contains several irregularly-shaped adipose tissue fragments which in aggregate measure ~2 x 1.5 x 0.5 cm. Several lymph node-like structures are identified ranging in size from 0.2 to 0.6 cm in greatest dimension. Entirely submitted as X3. Jar 1.

The seventh container is additionally labeled " " and contains several lymph nodes that range in size from 0.2 to ~1.3 cm in greatest dimension. Entirely submitted as " Jar 0.

The eighth container is additionally labeled "FS5B" and contains a single lymph node-like structure measuring ~2.9 cm in greatest dimension. Entirely submitted as Jar 0.

The ninth container is additionally labeled "X5" and contains multiple irregularly-shaped adipose tissue fragments which in aggregate measure ~4 x 3 x 1 cm. Upon examination, multiple lymph nodes are identified ranging in size from 0.2 cm to ~1.3 cm in greatest dimension. Entirely submitted as X5A and X5B. Jar 1.

The tenth container is additionally labeled "FS6" and contains two yellow-tan tissue fragments which in aggregate measure ~0.9 x 0.6 x 0.2 cm. Entirely submitted as FS6. Jar 0.

The eleventh container is additionally labeled "X6" and contains two irregularly-shaped adipose tissue fragments which in aggregate measure ~1 x 1 x 0.2 cm. No lymph node is identified. Entirely submitted as X6. Jar 0.

The twelfth container is additionally labeled "FS7" and contains a single lymph node measuring ~2 x 0.7 x 0.2 cm. Entirely submitted as FS7. Jar 0.

[page 5 of 7]
Surg. Path. No.:

Name:

GROSS (continued)

The thirteenth container is additionally labeled "X7" and contains two irregularly-shaped adipose tissue fragments which in aggregate measure ~0.7 x 0.7 x 0.2 cm. No lymph node is identified. Entirely submitted as X7. Jar 0.

The fourteenth container is additionally labeled "right parametrium" and contains a single irregularly-shaped adipose tissue fragment with two surgical staples. The specimen measures ~1 x 0.9 x 0.2 cm. After removal of the staples, the specimen is entirely submitted as RP. Jar 1.

The fifteenth container is additionally labeled "right common iliac lymph node" and contains a single irregularly-shaped adipose tissue fragment with two attached surgical staples. The specimen measures ~1 x 0.9 x 0.2 cm. No lymph node is identified. After removal of the staples, the specimen is entirely submitted as LN. Jar 0.

The sixteenth container is additionally labeled "uterus, cervix, BSO (radical hyst)." It contains a uterus with attached cervix, bilateral fallopian tubes, and ovaries. The uterus measures 7 cm from fundus to the lower uterine segment, 6 cm from cornu to cornu, and ~5.5 cm anterior posteriorly. The peritoneal reflection is smooth. The endometrial cavity measures 6 cm in length and ~2.5 cm from cornu to cornu. The endometrial cavity is pinkish-tan and shows a submucosal leiomyoma anteriorly, which measures ~2.5 x 2 x 1.5 cm. There are several well-circumscribed intramural leiomyomas identified ranging in size from 0.5 to ~1 cm in greatest dimension. All leiomyomas show uniform grayish-white cut surfaces with prominent whorling patterns and are rubbery firm in consistency. There is no hemorrhage, necrosis, or fleshy discolored areas identified. There is a large, fungating, focally ulcerated mass in the cervix which measures ~6.5 x 6 x 3 cm. The mass appears to arise from the transitional zone. The attached vaginal cuff is ~1.2 cm to the closest inked margin, anteriorly, and 1.3 cm posteriorly. After serial sectioning, tumor was found to be the most deeply invasive in the anterior cervix where it is ~0.5 cm to the closest inked non-peritonealized margin. No parametrial invasion is present. The myometrium averages ~2 cm in thickness. The right ovary measures 2.5 x 1.7 x 1.3 cm, with a grayish-pink, wrinkled external surface, and shows an unremarkable cut surface. The right fallopian tube measures 6.5 cm in length and averages ~0.5 cm in diameter. The serosal surface is grayish-pink, smooth, and grossly unremarkable. The left ovary measures 2.5 x 1.5 x 1.3 cm. The external surface is grayish-pink, wrinkled, and with focal areas of excision. The cut surface shows a cystic space filled with clear fluid and measures ~1.1 cm in diameter. The fallopian tube measures ~6.5 cm in length and averages ~0.5 cm in diameter. The serosal surface is grayish-pink,

[page 6 of 7]
Surg. Path. No.:

Name:

GROSS (continued)

with prominent congested vessels, smooth and otherwise unremarkable. There are a few peritubal cystic structures identified and range in size from 0.1 to 0.5 cm in diameter. Labeled VP - posterior vaginal cuff shave margin; VA - anterior vaginal cuff shave margin except for 1.0 cm on the left lateral aspect where it is submitted along with left parametrial soft tissue as radial margin, labeled LP1 through LP4; RP1 through RP4 - right parametrium; LP5 and LP6 - left parametrium; E1, E2, EC1, and C1 - contiguous sections of anterior uterus with attached cervix and vaginal cuff; C2 and C3 - two additional sections of anterior cervix; E3, E4, EC2, and C4 and C5 - contiguous sections of posterior uterus with attached cervix and vaginal cuff; C6 and C7 - additional sections of posterior cervix; RO - sections of right ovary; LO - section of left ovary; LT - sections of left fallopian tube. Jar 2.

COMMENT

A 6.2 cm moderately to poorly differentiated squamous cell carcinoma with focal keratinization is present in the cervix. The tumor is characterized by sheets and small nests of squamous cells infiltrating a desmoplastic stroma. In multifocal areas, there is marked nuclear pleomorphism. Extensive lymphovascular space invasion is identified. The tumor is predominantly exophytic, however, in areas on the left side, it invades to a depth of 10 mm where the total wall thickness measures 14 mm. No extension into parametrial soft tissue is identified. One parametrial lymph node is free of carcinoma. The separately submitted right parametrial biopsy is free of carcinoma. The vaginal cuff margin exhibits focal parakeratosis but no dysplasia or carcinoma is identified. Four right external iliac, three right obturator, two right external iliac (B), nine left pelvic, four periaortic, and one left common iliac lymph nodes are free of carcinoma. The entirely submitted specimen labeled "right common iliac lymph node" contains fibroadipose tissue with no carcinoma or lymphoid tissue identified.

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Squamous cell (epidermoid) carcinoma, invasive type
Keratinizing subtype
3. The MAXIMUM DEPTH OF TUMOR INVASION is 10 mm.
4. The BREADTH (MAXIMUM HORIZONTAL DIMENSION) OF THE TUMOR is 62 mm.
5. The TOTAL THICKNESS OF THE CERVIX is 14 mm.
6. Lymphatic invasion by tumor IS identified and is
WIDESPREAD.

[page 7 of 7]
HHH

Surg. Path. No.:

Name:

COMMENT (continued)

7. The NUCLEAR GRADE of the tumor is:
- 2 (Moderately-differentiated) to
- 3 (Poorly-differentiated)
8. The tumor DOES NOT invade through the entire thickness of the cervix to involve contiguous parametrial tissues.
9. The tumor DOES NOT involve the uterine corpus.
10. The tumor DOES NOT involve the vagina.
11. Metastasis to regional lymph nodes is ABSENT.
12. The total number of metastatically-involved nodes is 0.
13. The total number of regional nodes examined is 24.
14. Extracapsular extension of metastatic tumor through the lymph node capsule is NOT APPLICABLE; NO METASTASIS IS SEEN.
15. DETAILED STAGING INFORMATION:
- A. TUMOR GROWTH: THE PRIMARY NEOPLASM IS CLASSIFIED AS:

TNM SCHEME	FIGO SCHEME	DEFINITION
T1b	IB	Tumor confined to uterus but larger than T1a2/ IA2
- B. REGIONAL LYMPH NODES are classified as:
NO (Regional nodes are NOT involved by metastasis)
- C. DISTANT METASTASES: The status of distant tissues is:
X (Status cannot be assessed)
15. THE FINAL STAGE OF THE TUMOR IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

{End of Report}

Source: NCI Genomic Data Commons file d1ba36ea-1eba-4db7-9987-ecf54c9d87a5 (TCGA-EK-A2IR.2A0B2B7B-4EBC-49BC-929C-2E5AED2CCBC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).